Surgical pathology report (de-identified scan), TCGA case TCGA-BG-A0MS, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BG-A0MS-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: UTERUS WITH BILATERAL ADNEXA, 159.5 GRAMS, RADICAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY -

- A. POORLY DIFFERENTIATED ADENOCARCINOMA OF ENDOMETRIUM, ENDOMETRIOID TYPE, INVOLVING 90% OF ENDOMETRIAL SURFACE AND INVADING APPROXIMATELY 44% OF MYOMETRIUM (GRADE 3, STAGE 3B).
- B. FOCAL LYMPHOVASCULAR INVASION IDENTIFIED.
- C. ADENOCARCINOMA INVADES CERVICAL STROMA.
- D. BILATERAL OVARIES WITH PHYSIOLOGIC CHANGES, NEGATIVE FOR TUMOR.
- E. RIGHT PARAMETRIA WITH DETACHED FRAGMENTS OF TUMOR CONSISTENT WITH TISSUE CONTAMINATION (SEE COMMENT) AND WITH FRAGMENT OF FALLOPIAN TUBE.
- F. LEFT PARAMETRIA WITH DETACHED FRAGMENTS OF TUMOR CONSISTENT WITH TISSUE CONTAMINATION (SEE COMMENT) AND WITH TWO BENIGN LYMPH NODES (0/2).

PART 2: ANTERIOR VAGINAL MARGIN, EXCISION -
NEGATIVE FOR TUMOR.

PART 3: POSTERIOR VAGINAL MARGIN, EXCISION -
FOCAL ADENOCARCINOMA.

PART 4: RIGHT PELVIC LYMPH NODES, DISSECTION -
ONE OUT OF FIVE LYMPH NODES POSITIVE FOR METASTATIC CARCINOMA (1/5).

PART 5: RIGHT COMMON AND PERIAORTIC LYMPH NODES, DISSECTION -
SEVEN LYMPH NODES, NEGATIVE FOR TUMOR (0/7).

PART 6: LEFT PELVIC LYMPH NODE, DISSECTION -
ONE OUT OF FIVE LYMPH NODES POSITIVE FOR METASTATIC CARCINOMA (1/5).

PART 7: LEFT COMMON AND PERIAORTIC LYMPH NODES, DISSECTION -
ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

CASE SYNOPSIS:

SYNOPTIC - PRIMARY UTERINE ENDOMETRIAL TUMORS: HYSTERECTOMY SPECIMENS

TUMOR TYPE: Endometroid adenocarcinoma, NOS

HISTOLOGIC GRADE (epithelial neoplasm) [combined architectural and nuclear]:

Poorly differentiated (FIGO 3)

ARCHITECTURAL GRADE:

Poorly differentiated

NUCLEAR GRADE:

Grade 2

TUMOR SIZE:

Maximum dimension: 0.8 cm

PERCENT OF ENDOMETRIAL SURFACE INVOLVEMENT:

Anterior endomyometrium: 90 %, Posterior endomyometrium: 90 %

DEPTH OF INVASION**:

Less than 1/2 thickness of myometrium

STRUCTURES INVOLVED:

Cervical stroma, Vagina

MARGINS OF RESECTION:

Vaginal margin is positive for tumor

ANGIOLYMPHATIC INVASION:

Yes

LYMPH NODES POSITIVE:

Number of lymph nodes positive:: 2

LYMPH NODES EXAMINED:

Total number of lymph nodes examined: 18

LYMPH NODE GROUPS INVOLVED:

Pelvic lymph nodes, Right, Pelvic lymph nodes, Left

T STAGE, PATHOLOGIC:

pT3b

N STAGE, PATHOLOGIC:

pN1

M STAGE, PATHOLOGIC:

pMX

FIGO STAGE:

IIIB

for 5/3/11

Source: NCI Genomic Data Commons file 03aaf1ae-1683-455a-8157-b1565b4fe07c (TCGA-BG-A0MS.7BE89F2D-74E5-4D9E-8270-A216D79ADCD7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).